Somatic mutation profile of tumor specimen C3N-01214-03 (aliquot CPT0075560006) from CPTAC case C3N-01214, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.9 years (22,241 days).
Specimen C3N-01214-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edee2870-b095-4b91-89a0-1593917bbc92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01214-71 (Blood Derived Normal), aliquot CPT0075620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63d044ad-49ae-4bcb-a5e8-085addc0e674

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750502940, COSV101658616; called by muse, mutect2
- BAP1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 12/173 reads (7%) | catalogued as COSV56231807; called by muse, mutect2
- ENPEP | c.273del p.R92Dfs*15 | Frame Shift Del (DEL) | VAF 49/569 reads (9%) | catalogued as COSV99488267; called by mutect2, pindel
- FAM170A | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200551505; called by muse, mutect2
- FBN1 | c.6797A>G p.K2266R | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1566894294; called by muse, mutect2
- FMR1 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM148971, COSV54424185; called by muse, mutect2, varscan2
- MUC16 | c.3650T>C p.L1217P | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV67444047; called by muse, mutect2
- PCLO | c.11906A>T p.Y3969F | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.496); catalogued as rs1490499378; called by muse, mutect2
- TMEM151B | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs1203871431; called by muse, mutect2
- ANPEP | c.658T>C p.S220P | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- IMPDH1 | c.1494dup p.E499* (on ENST00000470772 / NM_001142573.2; = p.E585* on NM_000883.4) | Frame Shift Ins (INS) | VAF 72/590 reads (12%) | called by mutect2, pindel
- NTN5 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PCDHB1 | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP1R3C | c.858A>T p.L286F | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- RRBP1 | c.3546G>T p.E1182D (on ENST00000377813 / NM_001365613.2; = p.E749D on NM_004587.3) | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2
- SLC4A9 | c.2941T>A p.S981T (on ENST00000507527 / NM_001258428.2; = p.S957T on NM_031467.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SMC1B | c.1026T>A p.D342E | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.009); called by muse, mutect2
- TECRL | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2
- TNPO3 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- TNS4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- TOMM70 | c.292_300del p.H98_E100del | In Frame Del (DEL) | VAF 41/458 reads (9%) | called by mutect2, pindel
- TRPC6 | c.424G>C p.A142P | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- TTLL11 | c.1959G>C p.K653N | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UGT3A2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2
- VHL | c.622_629del p.H208Dfs*45 | Frame Shift Del (DEL) | VAF 42/520 reads (8%) | called by mutect2, pindel
- ADIPOR2 | c.606C>T p.H202= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs778643792; called by muse, mutect2
- ALKAL2 | c.384T>C p.P128= | Silent (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2
- NCL | c.1947T>C p.G649= | Silent (SNP) | VAF 39/554 reads (7%) | catalogued as rs763956578, COSV100502251; called by muse, mutect2
- RBM10 | c.156G>A p.E52= | Silent (SNP) | VAF 15/158 reads (9%) | catalogued as rs781831956; called by muse, mutect2, varscan2
- SPEM1 | c.741C>A p.V247= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1170G>A | RNA (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
